CCDI case PBCIJF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/63780b0f-d26a-4d96-8f05-0adb7bb1ac52

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 10.5 years (3,852 days).

Biospecimens (3 samples)
- Sample 0DSYE9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSYEG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSYEP: Tissue type: Tumor; Specimen type: Solid Tissue.
